Somatic mutation profile of tumor specimen TCGA-DK-A1A6-01A (aliquot TCGA-DK-A1A6-01A-11D-A13W-08) from TCGA case TCGA-DK-A1A6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 53.5 years (19,554 days).
Specimen TCGA-DK-A1A6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43865023-9b9f-48e9-891f-66b490cbaa75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1A6-10A (Blood Derived Normal), aliquot TCGA-DK-A1A6-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84081222-ebcf-4eb7-a78a-4226bcb9db7b

The open-access MAF lists 343 somatic variants for this specimen: 259 protein-altering or splice-affecting, 74 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 74, Nonsense Mutation 22, Splice Site 10, RNA 5, Intron 4, Frame Shift Ins 3, Nonstop Mutation 2, Splice Region 2, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 87/173 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.371dup p.C124Wfs*25 | Frame Shift Ins (INS) | VAF 78/133 reads (59%) | catalogued as rs1267047192, COSV53205177; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.93); catalogued as rs375671514, COSV55297373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACCS | c.221G>A p.W74* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99772748; called by muse, mutect2, varscan2
- ACTB | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 89/364 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59316730; called by muse, mutect2, varscan2
- ADAM19 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs755895049, COSV57423019; called by muse, varscan2
- ADAM22 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs752694897, COSV55969207; called by muse, mutect2, varscan2
- ADAM30 | c.1732C>G p.H578D | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV65560342; called by muse, mutect2, varscan2
- ADRA1A | c.366C>G p.I122M | Missense Mutation (SNP) | VAF 110/219 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52356845, COSV52357087; called by muse, mutect2, varscan2
- ADSS2 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV63696038; called by muse, mutect2, varscan2
- AGBL1 | c.2424C>A p.S808R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1430366786, COSV66848871; called by muse, mutect2
- AGL | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV54048224; called by muse, mutect2, varscan2
- ALPK1 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs762385585, COSV51581923; called by muse, mutect2, varscan2
- AMY2A | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 50/308 reads (16%) | catalogued as COSV101340623; called by muse, mutect2, varscan2
- ANK1 | c.5545G>C p.V1849L (on ENST00000347528 / NM_020477.3; = p.X1848_splice on NM_000037.4) | Missense Mutation (SNP) | VAF 48/459 reads (10%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV55872866; called by muse, mutect2, varscan2
- APOB | c.9692A>G p.D3231G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs778780703, COSV51923418; called by muse, mutect2, varscan2
- ARFGEF2 | c.1832G>A p.R611K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.297); catalogued as COSV64214746; called by muse, mutect2, varscan2
- ARHGEF19 | c.1284G>C p.K428N | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1199746111; called by muse, mutect2, varscan2
- AUTS2 | c.3506C>G p.S1169C | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV61383299; called by muse, mutect2, varscan2
- AVL9 | c.1946G>C p.*649Sext*13 | Nonstop Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100594545; called by muse, mutect2, varscan2
- BAAT | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs371212382; called by muse, mutect2, varscan2
- BORCS5 | c.155A>T p.D52V | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV53804591; called by muse, mutect2, varscan2
- BRD8 | c.2703G>C p.W901C | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV50145211; called by muse, mutect2, varscan2
- BRWD1 | c.4314C>G p.F1438L | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV60892728; called by muse, mutect2, varscan2
- BTBD7 | c.970T>C p.Y324H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54133888; called by muse, mutect2, varscan2
- BZW2 | c.1232-1G>C p.X411_splice | Splice Site (SNP) | VAF 20/83 reads (24%) | catalogued as COSV51753861; called by muse, mutect2, varscan2
- C1orf56 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs1461699890, COSV54845741; called by muse, varscan2
- C3 | c.3543G>A p.M1181I | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55568652; called by muse, mutect2, varscan2
- C9orf64 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 89/153 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV59032116; called by muse, mutect2, varscan2
- CCDC110 | c.1652A>G p.H551R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.463); catalogued as rs1197000498, COSV56869399; called by muse, mutect2, varscan2
- CCDC181 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs375735868; called by muse, mutect2, varscan2
- CCDC40 | c.2150C>G p.S717C | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV66472694; called by muse, mutect2, varscan2
- CCDC40 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 127/335 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV66472702; called by muse, mutect2, varscan2
- CCDC71 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 126/184 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58909742; called by muse, mutect2, varscan2
- CD248 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as rs200653218, COSV60935719; called by muse, mutect2, varscan2
- CDCA7L | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV100651146, COSV62258105; called by muse, mutect2, varscan2
- CFAP54 | c.5176C>G p.L1726V | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV61570579, COSV61572992; called by muse, mutect2, varscan2
- CH25H | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs1424643708, COSV64092195; called by muse, mutect2, varscan2
- CLASP1 | c.4589C>T p.S1530F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV55337369; called by muse, mutect2, varscan2
- COQ6 | c.1369C>G p.P457A | Missense Mutation (SNP) | VAF 112/219 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV53177932; called by muse, mutect2, varscan2
- CPS1 | c.2253G>C p.K751N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV51802122; called by muse, mutect2, varscan2
- CRACR2A | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52917622; called by muse, mutect2, varscan2
- CSMD1 | c.4041G>T p.K1347N (on ENST00000520002; = p.K1346N on NM_033225.6) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59288773, COSV59374130; called by muse, mutect2, varscan2
- CTAG2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 148/199 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55994023; called by muse, mutect2, varscan2
- DAGLA | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); catalogued as rs1409547344, COSV57193994; called by muse, mutect2, varscan2
- DBF4 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV55995841; called by muse, mutect2, varscan2
- DDC | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.234); catalogued as COSV63563711; called by muse, mutect2, varscan2
- DDX21 | c.2023C>G p.L675V | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV62555154; called by muse, mutect2, varscan2
- DHDDS | c.324-1G>A p.X108_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV52575451; called by muse, mutect2, varscan2
- DHX37 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 156/319 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1253670476, COSV58131924; called by muse, mutect2, varscan2
- DIDO1 | c.5471G>C p.R1824T | Missense Mutation (SNP) | VAF 499/868 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV56613790, COSV56619336; called by muse, mutect2, varscan2
- DNASE2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV53434443, COSV53435844; called by muse, mutect2, varscan2
- DST | c.4896G>C p.E1632D | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54997759, COSV99754072; called by muse, mutect2, varscan2
- DST | c.4762G>C p.E1588Q | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as rs1202435794, COSV54997767; called by muse, mutect2, varscan2
- EEA1 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59282612; called by muse, mutect2, varscan2
- EEFSEC | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1370773717, COSV54620147; called by muse, mutect2, varscan2
- EIF4G1 | c.2407G>C p.E803Q (on ENST00000346169 / NM_198241.3; = p.E608Q on NM_004953.5) | Missense Mutation (SNP) | VAF 125/450 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV59989182; called by muse, mutect2, varscan2
- ELAVL4 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV63914275; called by muse, mutect2, varscan2
- EMILIN2 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 133/273 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs753375646, COSV54421112; called by muse, mutect2, varscan2
- EP400 | c.4004C>T p.P1335L | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57762832; called by muse, mutect2, varscan2
- EPB41 | c.2416-1G>C p.X806_splice (on ENST00000343067 / NM_001166005.2; = p.X530_splice on NM_004437.4) | Splice Site (SNP) | VAF 36/128 reads (28%) | catalogued as COSV58040877; called by muse, mutect2, varscan2
- EPHB3 | c.2900G>T p.R967L | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100382769, COSV100382908; called by muse, mutect2, varscan2
- ESRP2 | c.1006G>C p.E336Q (on ENST00000565858 / NM_001365264.1; = p.E326Q on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52171951; called by muse, mutect2, varscan2
- ETV6 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1478954275, COSV67148178; called by muse, varscan2
- ETV6 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV67148182; called by muse, varscan2
- EXPH5 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV56198909; called by muse, mutect2
- EYA2 | c.156-1G>C p.X52_splice | Splice Site (SNP) | VAF 97/174 reads (56%) | catalogued as COSV57938469; called by muse, mutect2, varscan2
- FANCE | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs759034838, COSV57689081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD5 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53909026; called by muse, mutect2, varscan2
- FBXL7 | c.1294C>G p.R432G | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV100308779, COSV61651948; called by muse, mutect2, varscan2
- FBXO25 | c.338C>G p.S113* (on ENST00000382824 / NM_183421.2; = p.S46* on NM_012173.3) | Nonsense Mutation (SNP) | VAF 54/114 reads (47%) | catalogued as COSV99366822; called by muse, mutect2, varscan2
- FERMT2 | c.1020C>G p.D340E | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV58405126; called by muse, varscan2
- FREM2 | c.6763G>A p.E2255K | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as rs1185209837, COSV54828425, COSV54855715; called by muse, mutect2, varscan2
- FREM2 | c.6866G>C p.R2289T | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as rs777079243, COSV54828444; called by muse, mutect2, varscan2
- GABRB1 | c.1387C>T p.L463F | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV54970778; called by muse, mutect2, varscan2
- GABRG1 | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as COSV54952990, COSV99777656; called by muse, mutect2, varscan2
- GCC2 | c.2659C>G p.Q887E | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs775980873, COSV59174002; called by muse, mutect2, varscan2
- GPR89A | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as COSV100572397; called by muse, varscan2
- GRM3 | c.1970C>G p.S657* | Nonsense Mutation (SNP) | VAF 38/158 reads (24%) | catalogued as COSV100862303; called by muse, mutect2, varscan2
- H2AC13 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100704334; called by muse, mutect2, varscan2
- HARBI1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 136/371 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV56317448; called by muse, mutect2, varscan2
- HCFC1R1 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 108/406 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50187193; called by muse, mutect2, varscan2
- HECTD4 | c.4631G>A p.R1544K | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.209); catalogued as rs748817181, COSV66398524; called by muse, mutect2, varscan2
- HECTD4 | c.4282G>A p.E1428K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1246568193; called by muse, mutect2
- HLA-DRA | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV66622508; called by muse, mutect2, varscan2
- HMGA1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.932); catalogued as COSV61028958; called by muse, mutect2, varscan2
- HR | c.2375G>T p.R792L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769480349; called by muse, mutect2, varscan2
- HTRA3 | c.483G>A p.L161= | Splice Region (SNP) | VAF 40/85 reads (47%) | catalogued as COSV56469306; called by muse, mutect2, varscan2
- INSRR | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100947955, COSV63870918; called by muse, mutect2, varscan2
- IRF2BPL | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as COSV53146048; called by muse, mutect2, varscan2
- ITGA4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV52003493; called by muse, mutect2, varscan2
- ITPR3 | c.1398G>C p.Q466H | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV65405705; called by muse, mutect2, varscan2
- IVD | c.476G>A p.G159D (on ENST00000651168; = p.G156D on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 302/664 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM087373, COSV51098701; called by muse, mutect2, varscan2
- JAK3 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1471740073, COSV71685529; called by muse, mutect2, varscan2
- KCNU1 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV67753115; called by muse, mutect2, varscan2
- KHDRBS2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs771240471, COSV55427315; called by muse, mutect2, varscan2
- KIAA0319L | c.2326G>C p.D776H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57842004, COSV57851877; called by muse, mutect2, varscan2
- KLRC3 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67251398; called by muse, mutect2, varscan2
- KMT5B | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV58563729; called by muse, mutect2, varscan2
- LAMB2 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1131783, COSV59730824; called by muse, mutect2, varscan2
- LAMC1 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.695); catalogued as rs750433323, COSV51132544; called by muse, mutect2, varscan2
- LARGE1 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV61670709; called by muse, varscan2
- LARGE1 | c.930G>T p.M310I | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV61657808; called by muse, mutect2, varscan2
- LIPC | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54426636; called by muse, mutect2, varscan2
- LMNTD2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs374391484; called by muse, mutect2, varscan2
- LRFN5 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV53243340, COSV53258853; called by muse, mutect2, varscan2
- LRIT1 | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as COSV64511926, COSV64513711; called by muse, mutect2, varscan2
- LRRC6 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51537910; called by muse, mutect2, varscan2
- LTBP1 | c.3826C>G p.Q1276E (on ENST00000404816 / NM_206943.4; = p.Q950E on NM_000627.4) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as COSV55384547, COSV99698252; called by muse, mutect2, varscan2
- LTBP2 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761149592, COSV56204903; called by muse, mutect2, varscan2
- MAP3K13 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as rs763461574, COSV53983703; called by muse, mutect2, varscan2
- MAP3K21 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145103476; called by muse, mutect2, varscan2
- MAPK8IP1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53796676; called by muse, mutect2, varscan2
- MAPK9 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100558224; called by muse, mutect2, varscan2
- MARK4 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 73/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53468131; called by muse, mutect2, varscan2
- MBD6 | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 242/619 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV63072983; called by muse, mutect2, varscan2
- MEF2A | c.671G>A p.G224E (on ENST00000557942 / NM_001319206.2; = p.G226E on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1338970568, COSV57536836; called by muse, mutect2, varscan2
- MEGF6 | c.1520A>G p.E507G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs1257830199; called by muse, mutect2
- MON2 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV54803026; called by muse, mutect2, varscan2
- MRE11 | c.1326+1G>C p.X442_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as COSV60573877; called by muse, mutect2
- MROH8 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 214/771 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV54117260; called by muse, mutect2, varscan2
- MT1H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 75/381 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV60090520; called by muse, mutect2, varscan2
- MTIF2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55050203; called by muse, mutect2, varscan2
- MTO1 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64774835; called by muse, mutect2, varscan2
- MTRF1 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV65262834; called by muse, mutect2, varscan2
- MXD4 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as rs1218355505, COSV61465774; called by muse, mutect2, varscan2
- MXD4 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100455865; called by muse, mutect2, varscan2
- MYH7B | c.1566C>G p.I522M | Missense Mutation (SNP) | VAF 175/356 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53416555, COSV53421379; called by muse, mutect2, varscan2
- MYLK2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as COSV101044591, COSV65658512; called by muse, mutect2, varscan2
- MYO15A | c.804C>A p.S268R | Missense Mutation (SNP) | VAF 343/398 reads (86%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1392414832, COSV52751804; called by muse, mutect2, varscan2
- MYO5A | c.2096C>G p.S699* | Nonsense Mutation (SNP) | VAF 27/159 reads (17%) | catalogued as rs753464756, COSV100697481; called by muse, mutect2, varscan2
- MYPOP | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV56192879; called by muse, mutect2, varscan2
- MYT1L | c.1272C>A p.F424L | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV67708347, COSV67709367; called by muse, mutect2, varscan2
- NLRC5 | c.4203A>T p.E1401D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV52662143; called by muse, mutect2, varscan2
- NLRP9 | c.909G>C p.K303N | Missense Mutation (SNP) | VAF 118/143 reads (83%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV60459618; called by muse, mutect2, varscan2
- NOL12 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV63031633; called by muse, mutect2, varscan2
- NUTM2G | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs541253499, COSV63616879; called by muse, mutect2, varscan2
- OLFM4 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as rs1481205694, COSV54579927; called by muse, mutect2, varscan2
- OR52N4 | c.783C>G p.F261L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV57890271, COSV57893523; called by muse, mutect2, varscan2
- OR6C6 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV64455451, COSV64455971; called by muse, mutect2, varscan2
- OSBPL1A | c.2584G>C p.D862H (on ENST00000319481 / NM_080597.4; = p.D349H on NM_018030.4) | Missense Mutation (SNP) | VAF 82/149 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as COSV60195312; called by muse, mutect2, varscan2
- PAH | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); catalogued as rs868854935, COSV61013953; called by muse, mutect2, varscan2
- PCDH1 | c.3529G>C p.D1177H | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99745818; called by muse, varscan2
- PCDH10 | c.1140del p.F380Lfs*3 | Frame Shift Del (DEL) | VAF 171/394 reads (43%) | catalogued as COSV52087594, COSV52096631; called by mutect2, pindel, varscan2
- PCLO | c.11269A>G p.M3757V | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as rs764159984, COSV61616363; called by muse, mutect2, varscan2
- PCOLCE2 | c.1010C>G p.S337W | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2304735, COSV55997592; called by muse, mutect2, varscan2
- PDZD2 | c.2933G>C p.R978T | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV56850811; called by muse, mutect2, varscan2
- PHF20L1 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 81/154 reads (53%) | catalogued as COSV99620765; called by muse, mutect2, varscan2
- PKD1L1 | c.4795C>G p.L1599V | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1245542767, COSV56958004; called by muse, mutect2, varscan2
- PKD1L2 | c.773T>A p.M258K | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV61411645; called by muse, mutect2, varscan2
- PKHD1L1 | c.8173G>T p.A2725S | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65751248; called by muse, mutect2, varscan2
- PLCG1 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1434096207, COSV54815258, COSV99718437; called by muse, mutect2
- PLCXD2 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV67341983; called by muse, mutect2, varscan2
- PLIN3 | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 86/163 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV55734084; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs1450946602, COSV65046981; called by muse, varscan2
- PNLIPRP3 | c.1315A>C p.N439H | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV65046989; called by muse, varscan2
- POLE | c.5143G>A p.E1715K | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.716); catalogued as rs1368719601, COSV57673180, COSV57674238; called by muse, varscan2
- POLE | c.4883G>C p.G1628A | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1233643471, COSV57674250; called by muse, mutect2, varscan2
- PPP4R3B | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 64/103 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55401749; called by muse, mutect2, varscan2
- PRDM4 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs940716413, COSV57304478; called by muse, mutect2, varscan2
- PREX2 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | catalogued as COSV99906094; called by muse, mutect2, varscan2
- PRKD2 | c.2345A>G p.D782G | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1206670046, COSV52184534; called by muse, mutect2, varscan2
- PRKDC | c.9598C>G p.L3200V | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.082); catalogued as COSV58061664, COSV58067074; called by muse, mutect2, varscan2
- PRKDC | c.3127C>G p.Q1043E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58042868; called by muse, mutect2, varscan2
- PRPH | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.167); catalogued as COSV99142076; called by muse, mutect2, varscan2
- PSMB1 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1385123843, COSV51531784; called by muse, mutect2, varscan2
- PTPN21 | c.2749C>T p.R917* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as rs780993226, COSV60852584; called by muse, mutect2, varscan2
- PTPRT | c.2617G>T p.D873Y | Missense Mutation (SNP) | VAF 97/181 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61960753; called by muse, mutect2, varscan2
- PTPRZ1 | c.3761C>G p.S1254C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV66430348; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as rs779969064, COSV99424560; called by muse, mutect2, varscan2
- RABEP2 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 30/122 reads (25%) | catalogued as rs1269198047, COSV100706919; called by muse, mutect2, varscan2
- RANBP17 | c.2438C>A p.S813Y | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs749501219, COSV66656031, COSV66656916; called by muse, mutect2, varscan2
- RBFA | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51535061; called by muse, mutect2
- RBM14 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs369922357; called by muse, mutect2, varscan2
- RBM33 | c.1224C>G p.S408R | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs367916179; called by muse, mutect2, varscan2
- RIPOR1 | c.760G>C p.D254H (on ENST00000379312 / NM_001193522.2; = p.D250H on NM_024519.4) | Missense Mutation (SNP) | VAF 197/378 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50217237, COSV99242386; called by muse, mutect2, varscan2
- ROCK1 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as COSV101296291; called by muse, mutect2, varscan2
- RPGR | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV58832479, COSV58833345; called by muse, mutect2, varscan2
- RPS6 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.364); catalogued as COSV59548733; called by muse, mutect2, varscan2
- RYR2 | c.7565C>T p.T2522I | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as COSV63662245; called by muse, mutect2, varscan2
- SAMD9 | c.1255A>G p.K419E | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66072994; called by muse, mutect2, varscan2
- SASH1 | c.2599G>C p.E867Q | Missense Mutation (SNP) | VAF 214/338 reads (63%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV66558873; called by muse, mutect2, varscan2
- SEC16A | c.3352C>A p.Q1118K | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.52); PolyPhen benign (0.281); catalogued as rs1352549523; called by muse, mutect2, varscan2
- SETD4 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV59771160; called by muse, mutect2, varscan2
- SFPQ | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100599277; called by muse, mutect2, varscan2
- SFSWAP | c.521-1G>C p.X174_splice | Splice Site (SNP) | VAF 54/138 reads (39%) | catalogued as COSV55519449; called by muse, mutect2, varscan2
- SIRPG | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1281567353, COSV53805960; called by muse, mutect2, varscan2
- SLC22A12 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 102/527 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV60570831; called by muse, mutect2, varscan2
- SLC24A3 | c.1594G>C p.V532L | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60111673; called by muse, varscan2
- SLC33A1 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs149578822; called by muse, mutect2, varscan2
- SLC7A6OS | c.848G>C p.R283T | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV50449864; called by muse, mutect2, varscan2
- SLC9A4 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV54838402; called by muse, mutect2, varscan2
- SOSTDC1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752502638, COSV61048982; called by muse, mutect2, varscan2
- SPIDR | c.2282C>A p.P761Q | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52369630; called by muse, mutect2, varscan2
- SPTAN1 | c.2479C>T p.Q827* | Nonsense Mutation (SNP) | VAF 61/89 reads (69%) | catalogued as COSV63985980; called by muse, mutect2, varscan2
- ST8SIA3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 73/129 reads (57%) | PolyPhen probably damaging (0.993); catalogued as rs532770217, COSV60653316; called by muse, mutect2, varscan2
- STEAP4 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 60/119 reads (50%) | catalogued as rs554141706, COSV57328031; called by muse, mutect2, varscan2
- STK33 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.53); catalogued as COSV59396540; called by muse, mutect2, varscan2
- STK33 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.219); catalogued as COSV59396548, COSV59401196; called by muse, mutect2, varscan2
- STRA8 | c.136G>C p.E46Q (on ENST00000275764; = p.E24Q on NM_182489.2) | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV51963092, COSV99312716; called by muse, mutect2, varscan2
- SULT1C2 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 134/218 reads (61%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52263727; called by muse, varscan2
- SYMPK | c.1306C>G p.P436A | Missense Mutation (SNP) | VAF 102/166 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55609575; called by muse, mutect2, varscan2
- SYNE1 | c.3535G>A p.E1179K (on ENST00000367255 / NM_182961.4; = p.E1186K on NM_033071.3) | Missense Mutation (SNP) | VAF 75/115 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs775925423, COSV54907232; called by muse, mutect2, varscan2
- TAAR8 | c.636G>C p.M212I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV51585586; called by muse, mutect2, varscan2
- TBC1D16 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 217/566 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60475380; called by muse, mutect2, varscan2
- TECTA | c.3106T>G p.C1036G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50790316; called by muse, mutect2, varscan2
- TENM1 | c.7349T>C p.L2450S | Missense Mutation (SNP) | VAF 107/135 reads (79%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64425208; called by muse, mutect2, varscan2
- TFAP2A | c.193C>T p.Q65* (on ENST00000482890; = p.Q57* on NM_001032280.3) | Nonsense Mutation (SNP) | VAF 88/242 reads (36%) | catalogued as COSV100116695; called by muse, mutect2, varscan2
- TLK2 | c.1258G>A p.E420K (on ENST00000326270 / NM_001284333.2; = p.E398K on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV58300475; called by muse, mutect2, varscan2
- TM4SF19 | c.477G>A p.W159* | Nonsense Mutation (SNP) | VAF 28/170 reads (16%) | catalogued as rs1258599489; called by muse, mutect2, varscan2
- TMCO6 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 77/183 reads (42%) | catalogued as COSV99347054; called by muse, mutect2, varscan2
- TMPRSS15 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 391/466 reads (84%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV53034828; called by muse, mutect2, varscan2
- TNRC6C | c.1940C>T p.T647I | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs201217429, COSV56951981; called by muse, mutect2, varscan2
- TRMT13 | c.1101G>C p.M367I | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV61582667; called by muse, mutect2, varscan2
- TRPA1 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV51555483; called by muse, mutect2, varscan2
- TRPM6 | c.4610C>T p.A1537V | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV62502996; called by muse, mutect2, varscan2
- TSR1 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 108/441 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373777758, COSV52161251; called by muse, mutect2, varscan2
- TTBK2 | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV51157338; called by muse, mutect2, varscan2
- TTN | c.72671G>A p.G24224D (on ENST00000591111; = p.G16800D on NM_003319.4) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | PolyPhen benign (0.005); catalogued as rs756930121, COSV59889464; called by muse, mutect2, varscan2
- TTN | c.61898G>A p.R20633H (on ENST00000591111; = p.R13209H on NM_003319.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | PolyPhen probably damaging (0.998); catalogued as rs772979195, COSV60298564; called by muse, mutect2, varscan2
- TTN | c.25712A>G p.K8571R (on ENST00000591111; = p.K7644R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | PolyPhen benign (0.415); catalogued as COSV59926486, COSV60298598; called by muse, mutect2
- TYW3 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV63803273; called by muse, mutect2
- UBQLN2 | c.576G>C p.Q192H | Missense Mutation (SNP) | VAF 62/82 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57739035; called by muse, mutect2, varscan2
- ULBP1 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 152/227 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV57663489; called by muse, mutect2, varscan2
- USF3 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV57069834; called by muse, mutect2, varscan2
- USP53 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1308963191, COSV56792300; called by muse, mutect2, varscan2
- VIPR2 | c.1102-1G>A p.X368_splice | Splice Site (SNP) | VAF 102/171 reads (60%) | catalogued as rs1280385667, COSV51103354; called by muse, mutect2, varscan2
- WDHD1 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1388416561, COSV62212860; called by muse, mutect2, varscan2
- WDR41 | c.862C>G p.H288D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56997621; called by muse, mutect2, varscan2
- XPO7 | c.1275G>A p.L425= | Splice Region (SNP) | VAF 40/87 reads (46%) | catalogued as COSV53010725; called by muse, mutect2, varscan2
- YTHDF3 | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV101572369; called by muse, mutect2, varscan2
- ZBTB5 | c.1348C>G p.P450A | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV57038848; called by muse, mutect2, varscan2
- ZFHX4 | c.357A>C p.L119F | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as COSV50495653; called by muse, mutect2, varscan2
- ZIC1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 65/493 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51557333, COSV51558618, COSV99291351; called by muse, mutect2, varscan2
- ZNF500 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 120/250 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV54787041; called by muse, mutect2, varscan2
- ZNF624 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 96/188 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60938888; called by muse, mutect2, varscan2
- ZNF624 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV60938901; called by muse, varscan2
- ZNF624 | c.887G>C p.R296T | Missense Mutation (SNP) | VAF 93/161 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV60938972, COSV60941620; called by muse, mutect2, varscan2
- ZNF624 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60939037; called by muse, varscan2
- ZNF721 | c.1187A>C p.K396T (on ENST00000338977; = p.K408T on NM_133474.4) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV59089150; called by muse, mutect2, varscan2
- ZNF75A | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV73039560; called by muse, mutect2, varscan2
- ZNF99 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV68054748; called by muse, varscan2
- ZNF99 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68054753; called by muse, varscan2
- ZP4 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.105); catalogued as rs1021008107, COSV63910918; called by muse, varscan2
- ZPLD1 | c.1064C>T p.S355L (on ENST00000466937 / NM_001329788.1; = p.S371L on NM_175056.2) | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs369331610; called by muse, mutect2, varscan2
- ZSWIM8 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV67131097; called by muse, mutect2, varscan2
- ANO2 | c.1414G>A p.E472K (on ENST00000356134 / NM_001278597.3; = p.E476K on NM_001278596.3) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CPAMD8 | c.3286-1G>C p.X1096_splice (on ENST00000651564; = p.X1049_splice on NM_015692.5) | Splice Site (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- GPAT2 | c.2095A>C p.K699Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.165); called by muse, mutect2
- IGKC | c.324G>C p.*108Yext*59 | Nonstop Mutation (SNP) | VAF 52/86 reads (60%) | called by muse, mutect2, varscan2
- IRS2 | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- KDM6A | c.3875_3878+3del p.X1292_splice | Splice Site (DEL) | VAF 34/44 reads (77%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.336+7_336+8del p.X112_splice | Splice Site (DEL) | VAF 24/63 reads (38%) | called by pindel, varscan2
- PCDH1 | c.3493G>C p.E1165Q | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); called by muse, varscan2
- POGLUT1 | c.863C>A p.S288* | Nonsense Mutation (SNP) | VAF 37/266 reads (14%) | called by muse, varscan2
- PPP1R3C | c.327_337del p.W110Vfs*2 | Frame Shift Del (DEL) | VAF 102/179 reads (57%) | called by mutect2, pindel, varscan2
- QSER1 | c.5119C>T p.Q1707* (on ENST00000399302; = p.Q1836* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- TXNIP | c.979dup p.T327Nfs*14 | Frame Shift Ins (INS) | VAF 29/156 reads (19%) | called by mutect2, pindel, varscan2
- ZNF624 | c.756dup p.G253Rfs*19 | Frame Shift Ins (INS) | VAF 97/260 reads (37%) | called by pindel, varscan2
- ACAD10 | c.2112C>T p.L704= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV58162355; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2365C>T p.L789= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV54436312, COSV54459568; called by muse, mutect2
- BMP1 | c.765G>A p.Q255= | Silent (SNP) | VAF 113/513 reads (22%) | catalogued as COSV60476319; called by muse, mutect2, varscan2
- CASZ1 | c.817C>T p.L273= | Silent (SNP) | VAF 146/296 reads (49%) | catalogued as COSV59732068; called by muse, mutect2, varscan2
- CATSPERG | c.3183C>T p.L1061= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as rs373710337; called by muse, mutect2, varscan2
- CCT8L2 | c.1440G>A p.V480= | Silent (SNP) | VAF 119/349 reads (34%) | catalogued as COSV63461634, COSV63462331; called by muse, mutect2, varscan2
- CEP112 | c.1176G>A p.L392= | Silent (SNP) | VAF 45/268 reads (17%) | catalogued as rs1420689190, COSV67144284; called by muse, mutect2, varscan2
- CFAP54 | c.5310C>T p.F1770= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs768774190, COSV61570582; called by muse, mutect2, varscan2
- CHRNA4 | c.873C>G p.L291= | Silent (SNP) | VAF 78/548 reads (14%) | catalogued as COSV64720938; called by muse, mutect2, varscan2
- CNTN2 | c.2928C>T p.D976= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV59348109; called by muse, mutect2, varscan2
- COL6A2 | c.201C>G p.L67= | Silent (SNP) | VAF 54/239 reads (23%) | catalogued as COSV55998820; called by muse, mutect2, varscan2
- CRP | c.480C>T p.F160= | Silent (SNP) | VAF 120/383 reads (31%) | catalogued as rs374947007, COSV54812594; called by muse, mutect2, varscan2
- CRTC2 | c.1800C>T p.F600= | Silent (SNP) | VAF 122/243 reads (50%) | catalogued as COSV57841052, COSV57841860; called by muse, mutect2, varscan2
- CSTF2 | c.955C>A p.R319= | Silent (SNP) | VAF 100/116 reads (86%) | catalogued as COSV65893447, COSV65895238; called by muse, mutect2, varscan2
- DNAH5 | c.1518C>T p.D506= | Silent (SNP) | VAF 47/84 reads (56%) | catalogued as COSV54204254; called by muse, mutect2, varscan2
- DOCK2 | c.5184G>A p.E1728= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV56942186; called by muse, mutect2, varscan2
- DOT1L | c.2931C>T p.T977= | Silent (SNP) | VAF 104/224 reads (46%) | catalogued as rs762151259, COSV67107968; called by muse, mutect2, varscan2
- F5 | c.2391C>G p.A797= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as COSV63120476; called by muse, mutect2, varscan2
- FADS6 | c.402C>T p.F134= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs1357030614, COSV59603038; called by muse, mutect2, varscan2
- FAM47A | c.1737C>T p.Y579= | Silent (SNP) | VAF 45/56 reads (80%) | catalogued as COSV60494016; called by muse, mutect2, varscan2
- FLG | c.11331G>A p.S3777= | Silent (SNP) | VAF 145/634 reads (23%) | catalogued as rs147295587, COSV64240789; called by muse, mutect2, varscan2
- FLT1 | c.663C>G p.L221= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV56717848; called by muse, mutect2, varscan2
- GALNT6 | c.1014G>A p.E338= | Silent (SNP) | VAF 69/178 reads (39%) | catalogued as COSV62541623; called by muse, mutect2, varscan2
- GBX1 | c.1091G>A p.*364= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs750469482, COSV52546756; called by muse, mutect2, varscan2
- GRB14 | c.822G>A p.P274= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as rs200051864, COSV55742355; called by muse, mutect2, varscan2
- GRID1 | c.2478C>G p.L826= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV60045867; called by muse, mutect2, varscan2
- HAUS8 | c.753C>T p.S251= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as COSV53725283; called by muse, mutect2, varscan2
- HIRIP3 | c.1670G>A p.*557= | Silent (SNP) | VAF 71/134 reads (53%) | catalogued as COSV99662929; called by muse, mutect2, varscan2
- HUWE1 | c.9144G>A p.Q3048= | Silent (SNP) | VAF 44/61 reads (72%) | catalogued as COSV53332889, COSV53343427; called by muse, varscan2
- ISYNA1 | c.1434G>T p.A478= | Silent (SNP) | VAF 34/528 reads (6%) | catalogued as COSV54212184, COSV99526007; called by muse, mutect2
- ITPRIPL2 | c.189C>A p.L63= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV67348047; called by muse, mutect2
- KCNJ11 | c.333C>T p.V111= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV60594164; called by muse, mutect2, varscan2
- LEXM | c.726G>C p.R242= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV64022049; called by muse, mutect2, varscan2
- MAGEA4 | c.234C>T p.F78= | Silent (SNP) | VAF 91/117 reads (78%) | catalogued as COSV52340234; called by muse, mutect2, varscan2
- MYCT1 | c.417G>C p.L139= | Silent (SNP) | VAF 61/91 reads (67%) | catalogued as COSV65890806; called by muse, mutect2, varscan2
- MYPN | c.1596G>C p.V532= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as COSV62731601; called by muse, mutect2, varscan2
- NAT9 | c.501C>T p.S167= | Silent (SNP) | VAF 90/235 reads (38%) | catalogued as COSV52852515; called by muse, mutect2, varscan2
- NDRG4 | c.291C>G p.P97= (on ENST00000570248 / NM_001378344.1; = p.P129= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 240/470 reads (51%) | catalogued as COSV50746425, COSV50748169; called by muse, varscan2
- NLRP9 | c.1041G>A p.V347= | Silent (SNP) | VAF 222/261 reads (85%) | catalogued as rs146611098, COSV60459598; called by muse, mutect2, varscan2
- NTRK3 | c.1188C>T p.L396= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as rs1250541353, COSV58139868; called by muse, mutect2, varscan2
- OR10C1 | c.669C>A p.L223= (on ENST00000622521; = p.L221= on NM_013941.3) | Silent (SNP) | VAF 68/337 reads (20%) | catalogued as COSV65822243, COSV65822605; called by muse, mutect2, varscan2
- OR52E2 | c.977G>A p.*326= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV58613034; called by muse, mutect2, varscan2
- OTUD4 | c.1812T>C p.F604= (on ENST00000447906 / NM_001366057.1; = p.F539= on NM_001102653.1) | Silent (SNP) | VAF 59/241 reads (24%) | catalogued as rs375195266; called by muse, mutect2, varscan2
- OVGP1 | c.382C>T p.L128= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV63857534; called by muse, mutect2
- P2RX3 | c.15C>T p.S5= | Silent (SNP) | VAF 134/412 reads (33%) | catalogued as rs748037477, COSV53478229; called by muse, mutect2, varscan2
- PCDHGA3 | c.1779G>A p.A593= | Silent (SNP) | VAF 125/467 reads (27%) | catalogued as COSV53928592; called by muse, mutect2, varscan2
- PFDN6 | c.84G>A p.S28= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV65841932; called by muse, mutect2, varscan2
- PLAGL2 | c.1488G>A p.Q496= | Silent (SNP) | VAF 58/277 reads (21%) | catalogued as rs751194796, COSV55789629; called by muse, mutect2, varscan2
- PLCB1 | c.1056G>C p.V352= | Silent (SNP) | VAF 123/164 reads (75%) | catalogued as COSV62038396; called by muse, mutect2, varscan2
- PTPRD | c.747A>T p.P249= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV61928720; called by muse, mutect2, varscan2
- RBM4 | c.309G>A p.P103= | Silent (SNP) | VAF 198/353 reads (56%) | catalogued as rs775441815, COSV59518051; called by muse, mutect2, varscan2
- SCO2 | c.663C>A p.I221= | Silent (SNP) | VAF 80/542 reads (15%) | catalogued as COSV52689238; called by muse, mutect2, varscan2
- SCTR | c.1074C>T p.F358= | Silent (SNP) | VAF 36/195 reads (18%) | catalogued as rs140245245; called by muse, mutect2, varscan2
- SDK1 | c.2397G>T p.G799= | Silent (SNP) | VAF 97/200 reads (49%) | catalogued as rs202017032, COSV67356699; called by muse, mutect2, varscan2
- SEC13 | c.201C>T p.H67= (on ENST00000350697 / NM_183352.3; = p.H70= on NM_030673.4) | Silent (SNP) | VAF 32/233 reads (14%) | catalogued as rs1217147600, COSV61601220; called by muse, mutect2, varscan2
- SHISA3 | c.477C>T p.S159= | Silent (SNP) | VAF 110/435 reads (25%) | catalogued as COSV59979427; called by muse, mutect2, varscan2
- SLC2A1 | c.1014C>T p.L338= | Silent (SNP) | VAF 67/217 reads (31%) | catalogued as COSV65286713; called by muse, mutect2, varscan2
- SLIT1 | c.3918C>T p.N1306= | Silent (SNP) | VAF 81/498 reads (16%) | catalogued as rs148583876; called by muse, mutect2, varscan2
- SLIT1 | c.708C>T p.I236= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs900242418, COSV99820935; called by muse, mutect2, varscan2
- SPEG | c.8070C>T p.Y2690= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1459713350; called by muse, mutect2, varscan2
- SPTAN1 | c.2286C>T p.L762= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as rs745436802, COSV63985443; called by muse, mutect2, varscan2
- TEK | c.600C>T p.T200= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV66227468; called by muse, mutect2, varscan2
- TPCN1 | c.465C>T p.L155= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV59232339; called by muse, mutect2, varscan2
- TRIM27 | c.126C>T p.R42= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV65874028; called by muse, mutect2
- TRMT2A | c.1515C>T p.L505= | Silent (SNP) | VAF 107/334 reads (32%) | catalogued as rs762744801, COSV52812359; called by muse, mutect2, varscan2
- TXNRD2 | c.1026G>A p.L342= | Silent (SNP) | VAF 166/409 reads (41%) | catalogued as rs777442456, COSV68691442; called by muse, mutect2, varscan2
- UBC | c.1953G>A p.L651= | Silent (SNP) | VAF 128/617 reads (21%) | catalogued as rs777328392, COSV60061184; called by muse, mutect2, varscan2
- USP35 | c.147C>T p.Y49= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2
- XIRP2 | c.5037G>A p.Q1679= (on ENST00000628543; = p.Q1854= on NM_152381.6) | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV54682900; called by muse, mutect2, varscan2
- ZBTB46 | c.408C>T p.D136= | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as rs370304894; called by muse, mutect2, varscan2
- ZCCHC4 | c.765C>T p.A255= | Silent (SNP) | VAF 57/167 reads (34%) | catalogued as COSV57180230; called by muse, mutect2, varscan2
- ZNF274 | c.1887C>A p.T629= (on ENST00000610905; = p.T524= on NM_016324.3) | Silent (SNP) | VAF 48/463 reads (10%) | catalogued as COSV58766601; called by muse, mutect2, varscan2
- ZNF33B | c.2292C>T p.L764= | Silent (SNP) | VAF 32/270 reads (12%) | catalogued as rs775002083, COSV63943245; called by muse, mutect2, varscan2
- ZNF703 | c.258G>A p.K86= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1266940502; called by muse, mutect2
- BSDC1 | c.1260+106C>G | Intron (SNP) | VAF 34/72 reads (47%) | catalogued as COSV61983186; called by muse, mutect2, varscan2
- CALCOCO1 | c.1898+285C>A | Intron (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- CCDC140 | n.474G>A | RNA (SNP) | VAF 43/112 reads (38%) | catalogued as COSV54676629; called by muse, mutect2, varscan2
- CCN6 | c.-23-20G>T | Intron (SNP) | VAF 80/136 reads (59%) | catalogued as COSV57888756; called by muse, mutect2, varscan2
- CD48 | c.*1G>A | 3'UTR (SNP) | VAF 32/58 reads (55%) | catalogued as COSV100924203; called by muse, mutect2, varscan2
- EEF1D | c.-7-2778G>A | Intron (SNP) | VAF 90/132 reads (68%) | catalogued as COSV57817543; called by muse, mutect2, varscan2
- MIR545 | n.26C>T | RNA (SNP) | VAF 26/34 reads (76%) | called by muse, mutect2, varscan2
- NBPF25P | n.1423C>G | RNA (SNP) | VAF 69/371 reads (19%) | called by muse, mutect2, varscan2
- SNORD115-40 | n.66G>A | RNA (SNP) | VAF 160/495 reads (32%) | catalogued as rs757427516; called by muse, mutect2, varscan2
- SNORD115-40 | n.67G>A | RNA (SNP) | VAF 157/488 reads (32%) | called by muse, mutect2, varscan2
